Surgical pathology report (de-identified scan), TCGA case TCGA-30-1853, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1853-01A (Primary Tumor).

[page 1 of 2]
Accession Number: [REDACTED] Report Status: Final
Type: Surgical Pathology
Pathology Report [REDACTED] SOFT TISSUE TUMOR EXTENSIVE RESECTION
Accessioned On: [REDACTED]

DIAGNOSIS:

SPECIMEN LABELED "OMENTAL TUMOR":
METASTATIC PAPILLARY SEROUS CARCINOMA.

TCGA-30-1853

SPECIMEN LABELED "RIGHT ADNEXA":
PAPILLARY SEROUS ADENOCARCINOMA of the ovary, poorly differentiated, with
surface involvement and extension into mesosalpinx.
Endometriosis involving mesosalpinx.

SPECIMEN LABELED "LEFT ADNEXA":
PAPILLARY SEROUS ADENOCARCINOMA of the ovary, poorly differentiated, with
surface involvement.
The tumor is associated with an adenofibroma and does not involve the
fallopian tube.

SPECIMEN LABELED "UTERUS AND CERVIX":
Atrophic endometrium.
Leiomyoma.

CLINICAL DATA:

History: [REDACTED] with ovarian masses and cysts.
Clinical Diagnosis: ? ovarian cancer.

TISSUE SUBMITTED: 1. Omentum tumor. [REDACTED]

2. Right adnexa. [REDACTED]

3. Left adnexa. [REDACTED]

4. Uterus and cervix.

O.R. CONSULTATION:

SPECIMEN LABELLED "#1 OMENTAL TUMOR"(FSA):
Papillary carcinoma, favor serous type.

SPECIMEN LABELLED "#2 RIGHT ADNEXA"(FSB):
Papillary carcinoma, favor serous type.

SPECIMEN LABELLED "#3 LEFT ADNEXA"(FSC):
Papillary carcinoma, favor serous type.

CYTOLOGY:

PERITONEAL FLUID

CELL BLOCK AND CYTOLOGY [REDACTED]

SUSPICIOUS CELLS PRESENT.

Few clusters of atypical epithelial cells, suspicious for adenocarcinoma.
(Best seen on cytology preparations).

The specimen, labeled "peritoneal fluid", consists of [REDACTED] of orange/red fluid
[REDACTED] The fluid is centrifuged, and the remaining cell
pellet, measuring 1.0 cm, is submitted in formalin for cell block sections.

Micro CB: peritoneal fluid, multi frags, 1 cass, [REDACTED]

GROSS DESCRIPTION:

The specimen is received fresh, in four parts, labelled with the patient's
name and unit number.

Part one, "omental tumor", consists of an irregular fragment of fibrofatty
tissue measuring 21 x 12 x 6.5 cm. The external surface of the specimen is
irregular, bosselated, focally hemorrhagic. The cut surface of the specimen
shows a 12.5 x 11 x 7 cm yellow/tan soft, extensively hemorrhagic and necrotic
tumor mass. The central portion of the lesion shows a glistening area of
possible degeneration. The tumor mass is surrounded by a rim of mature adipose
tissue. A representative section of the tumor mass is submitted for [REDACTED]

Micro 1-3: tumor mass, 3 f, [REDACTED]

Micro 4: fibroadipose tissue, 1 f, [REDACTED]

Micro 16: remnant FSA, 1 f, [REDACTED]

[page 2 of 2]
Part two, "right adnexa", consists of a fragmented irregular ovary measuring 8.5 x 8 x 2.5 cm with attached non-fimbriated fallopian tube measuring 8 cm in length and ranging in diameter from 2.5 cm to 0.5 cm. The external surface of the fallopian tube is red/tan, focally hemorrhagic. The distal portion of the fallopian shows a 3 x 2.5 x 2 cm firm nodule. The cut surface of the nodule is yellow/tan, focally hemorrhagic and necrotic. The mid-portion of the fallopian tube is dilated up to 1.5 cm in diameter. The area of dilatation is filled with hemorrhagic fluid. The external surface of the the ovary is irregular, focally hemorrhagic. Multiple yellow/tan, raised soft nodules are identified, the largest of which measures 3.5 x 3 x 2 cm. The cut surface of the ovary (previously opened) shows few cavities. The internal surface of one of the cavities identified shows a 1.2 x 1 x 0.2 cm area of yellow/tan soft papillary projections. The internal surface of the other cavities is predominantly smooth and glistening with focal areas of hemorrhage. Received also is a 5.5 x 3.5 x 3.2 cm irregular nodule of yellow/tan soft tissue, detached from the rest of the specimen. The cut surface of the nodules is pink/grey, fleshy with focal areas of hemorrhage. A representative section of one of the ovarian is submitted for [REDACTED]

Micro 5-6: tubal nodule, 2 f, [REDACTED]
Micro 7: fallopian tube with area of cystic dilatation, 2 [REDACTED]
Micro 8-12: solid nodules on the ovarian surface, mult frags, [REDACTED]
Micro 13: area with papillary projections, 2 f, [REDACTED]
Micro 14: nodules received separated from the rest of the specimen, 1 f, [REDACTED]
Micro 15: remnant of FSB, 1 f, [REDACTED]

Part three, "left adnexa", consists of a 6 x 4 x 3 cm fragment of tissue with an irregular surface. A fallopian tube with a fimbriated end is identified and measures 4.5 cm in length x 0.8 cm in largest diameter. The attached adnexal mass consists mostly of a nodule with a papillary/irregular surface and a cyst containing both cystic and solid elements. Both the solid nodule and the cystic nodules have been cut. The solid nodule measures 3.2 x 2.5 x 2.8 cm and the cystic mass measures 2.5 cm in the largest diameter.

Micro 17: FSCR, 1 f, [REDACTED]
Micro 18: sections of fallopian tube, 3 f, [REDACTED]
Micro 19-20: sections of solid nodules, 2 f, [REDACTED]
Micro 21-22: sections of cystic mass, 2 f, [REDACTED]

Part four, "uterus with cervix", consists of a 50 gm hysterectomy. The uterus and cervix measures 7 x 5 x 3 cm in overall dimensions having a smooth, glistening and focally hemorrhagic serosal surface. The tan, smooth and glistening exocervix (3.3 cm in diameter) has a slit-like os (1.5 cm in diameter). The specimen is inked prior to processing. The endocervix (2.1 cm in length x 1.4 cm in width) has a smooth and glistening surface with a 0.6 cm fluid filled cyst. The endometrium (2.1 cm from cornu to cornu x 3.8 cm in length x 0.1 cm in thickness) is smooth and glistening with focal mucosal hemorrhages. The myometrium (1.4 cm in maximal thickness) contains a single small intramural white nodule measuring 0.3 cm in diameter.

Micro 23: anterior cervix, 1 f, [REDACTED]
Micro 24: posterior cervix, 1 f, [REDACTED]
Micro 25: posterior lvs, 1 f, [REDACTED]
Micro 26-27: anterior endometrium and serosa, 2 [REDACTED]
Micro 28-29: posterior endometrium and serosa, 1 [REDACTED]
Micro 30: section of myometrial nodule, 1 f, [REDACTED]

ports to: [REDACTED]

SPECIMEN TYPE: SOFT TISSUE TUMOR EXTENSIVE RESECTION
ADDITIONAL SPECIMEN TYPE: UTERUS WITH OR WITHOUT TUBES & OVARIES, NEOPLASTIC
ADDITIONAL SPECIMEN TYPE: CELL BLOCK (ANY SOURCE)

Source: NCI Genomic Data Commons file d19cdf97-6436-4c09-a6a1-e0c750ceb352 (TCGA-30-1853.DED9BA4C-8D3D-450B-A345-772A3E3AE288.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).